CCDI case PBCNXK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/d7b2be5e-7645-406f-a64e-75b8606257ca

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 3.8 years (1,401 days).

Biospecimens (2 samples)
- Sample 0DWODM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWODT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
